Somatic mutation profile of tumor specimen HCM-CSHL-0459-C17-01B (aliquot HCM-CSHL-0459-C17-01B-01D-A79C-36) from HCMI case HCM-CSHL-0459-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.4 years (20,980 days).
Specimen HCM-CSHL-0459-C17-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c767c23-4049-43af-9913-b9207bc9a343.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0459-C17-10A (Blood Derived Normal), aliquot HCM-CSHL-0459-C17-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a5ab9a6-128b-49b7-9e44-3914f07c6bc7

The open-access MAF lists 2,612 somatic variants for this specimen: 1,886 protein-altering or splice-affecting, 651 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,496, Silent 651, Frame Shift Del 198, Nonsense Mutation 75, Frame Shift Ins 71, Intron 41, Splice Region 25, 3'UTR 14, Splice Site 10, In Frame Del 8, 5'Flank 6, 5'UTR 6.

Variants (750 of 2,612; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 106/365 reads (29%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, varscan2
- ABCD1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201568579, CM000643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 83/409 reads (20%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1371del p.K457Nfs*17 | Frame Shift Del (DEL) | VAF 64/366 reads (17%) | catalogued as rs1085307340; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA1 | c.668del p.K223Rfs*11 | Frame Shift Del (DEL) | VAF 84/352 reads (24%) | catalogued as rs80357537, CD057384, CS1211735; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.5583del p.V1862* | Frame Shift Del (DEL) | VAF 44/232 reads (19%) | catalogued as rs397507790, COSV66450671; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 81/397 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITPR1 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 74/378 reads (20%) | catalogued as rs886058579, COSV56974596; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 62/313 reads (20%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, varscan2
- LZTR1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs587777177, CM140924, COSV99301371; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs63751113, CM021636, COSV52275309, COSV52291664; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 109/465 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1554263326, COSV100640958, COSV61822452, COSV61823434; ClinVar: pathogenic; called by muse, mutect2
- RNF43 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 56/230 reads (24%) | hotspot (GDC flag); catalogued as rs786205215, CM154177, COSV68457376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPH4A | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 89/485 reads (18%) | catalogued as rs1034327724, COSV57633705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 82/286 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58822445, COSV58825728, COSV58829155; called by mutect2, varscan2
- SYNE1 | c.24284G>A p.R8095H (on ENST00000367255 / NM_182961.4; = p.R8024H on NM_033071.3) | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs119103246, CM075027, COSV54948375; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6327dup p.G2110Wfs*3 (on ENST00000272895 / NM_173076.3; = p.G1792Wfs*3 on NM_015657.3) | Frame Shift Ins (INS) | VAF 104/466 reads (22%) | catalogued as rs1204636023; called by mutect2, varscan2
- ABCA7 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.513); catalogued as rs756112727; called by muse, mutect2, varscan2
- ABCA9 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 112/476 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs764821055, COSV60622467; called by muse, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 174/720 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABCF1 | c.1145G>A p.R382Q (on ENST00000326195 / NM_001025091.2; = p.R344Q on NM_001090.3) | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs749772013; called by muse, mutect2, varscan2
- ABCG1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs564812607; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144857039; called by muse, mutect2, varscan2
- ABHD8 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1257742043; called by muse, mutect2, varscan2
- ABL1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 70/453 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs370646520, COSV59325808; called by muse, mutect2, varscan2
- ABLIM3 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV58642691; called by muse, mutect2, varscan2
- ABO | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs377147187; called by muse, mutect2, varscan2
- ABRA | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 92/465 reads (20%) | catalogued as rs765786301; called by muse, mutect2, varscan2
- AC013489.1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 110/520 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs780142606; called by muse, mutect2, varscan2
- ACACB | c.7097C>T p.T2366M | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs754980151, COSV58131584; called by muse, mutect2, varscan2
- ACADS | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54370327; called by muse, mutect2, varscan2
- ACAP3 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1319532754; called by muse, varscan2
- ACIN1 | c.3989G>A p.R1330Q | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs746023844, COSV99399692; called by muse, varscan2
- ACO1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 71/366 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328936319, COSV104401460; called by muse, mutect2, varscan2
- ACOT7 | c.811G>A p.V271I (on ENST00000377855 / NM_181864.3; = p.V261I on NM_007274.4) | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs781767639; called by muse, mutect2, varscan2
- ACOX3 | c.876C>T p.D292= | Splice Region (SNP) | VAF 42/133 reads (32%) | catalogued as rs751029086; called by muse, mutect2, varscan2
- ACP7 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs546523874, COSV58700546; called by muse, varscan2
- ACSF3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs144411003; called by muse, mutect2
- ACSM3 | c.1385G>T p.R462I | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55503011; called by muse, mutect2, varscan2
- ACSS1 | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241493290; called by muse, mutect2, varscan2
- ACTN2 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1057523721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs201452185; ClinVar: benign; called by muse, mutect2, varscan2
- ADAD1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 107/467 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314917408; called by muse, mutect2, varscan2
- ADAMTS10 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.595); catalogued as rs782813134, COSV54353240; called by muse, mutect2, varscan2
- ADAMTS17 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.956); catalogued as rs377436249; called by muse, mutect2, varscan2
- ADAMTS4 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 67/367 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs767813779; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1233835454, COSV63203957; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.131); catalogued as rs886063646, COSV63204764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB1 | c.1601G>A p.R534H (on ENST00000360697 / NM_001346687.2; = p.R494H on NM_001112.4) | Missense Mutation (SNP) | VAF 96/413 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs201477864; called by muse, mutect2, varscan2
- ADCK5 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1222242540, COSV100450487; called by muse, mutect2, varscan2
- ADCY2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767957240; called by muse, mutect2, varscan2
- ADCY2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100603438; called by muse, mutect2, varscan2
- ADGRD1 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs1221659296; called by muse, mutect2, varscan2
- ADGRL3 | c.3091del p.V1031Cfs*39 (on ENST00000506720 / NM_001322402.2; = p.V963Cfs*39 on NM_015236.6) | Frame Shift Del (DEL) | VAF 112/518 reads (22%) | catalogued as COSV104438836; called by mutect2, varscan2
- ADGRL3 | c.4534G>A p.E1512K (on ENST00000506720 / NM_001322402.2; = p.E1401K on NM_015236.6) | Missense Mutation (SNP) | VAF 91/456 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.228); catalogued as rs751513777, COSV72231753; called by muse, mutect2, varscan2
- ADORA3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766923748, COSV53986544; called by muse, mutect2, varscan2
- ADPRS | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1293906648, COSV52882351; called by muse, mutect2, varscan2
- AEBP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764745972, COSV56261407; called by muse, mutect2, varscan2
- AFF4 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 97/456 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.027); catalogued as rs1312528517; called by muse, mutect2, varscan2
- AGO1 | c.49dup p.L17Pfs*28 | Frame Shift Ins (INS) | VAF 56/237 reads (24%) | catalogued as rs752471592; called by mutect2, varscan2
- AGO4 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs750167672; called by muse, mutect2, varscan2
- AGRN | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV101038734; called by muse, mutect2, varscan2
- AGRN | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs757377436; called by muse, mutect2, varscan2
- AHDC1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs201616346; called by muse, varscan2
- AIFM3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs553803201; called by muse, mutect2
- AIPL1 | c.784+4C>T | Splice Region (SNP) | VAF 39/225 reads (17%) | catalogued as rs375600133; called by muse, mutect2, varscan2
- AKAP17A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs775070085, COSV58312051; called by muse, mutect2, varscan2
- AKAP9 | c.6073C>T p.Q2025* (on ENST00000359028; = p.Q1993* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/308 reads (17%) | catalogued as rs786205714, COSV62345120; called by muse, mutect2, varscan2
- AL121899.2 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs762552709, COSV67351217; called by muse, mutect2, varscan2
- ALAS2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs772482624, CM1312006, COSV58190490; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALDH2 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs751980357, COSV55669488; called by muse, mutect2, varscan2
- ALDH3A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs750383473, COSV56736817; called by muse, mutect2, varscan2
- ALG10B | c.980del p.L327Wfs*5 | Frame Shift Del (DEL) | VAF 63/320 reads (20%) | catalogued as COSV58145139; called by mutect2, varscan2
- ALOX5 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1312171446; called by muse, mutect2, varscan2
- ALPK2 | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 126/589 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs147290810; called by muse, mutect2, varscan2
- ALPP | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs755793283, COSV101235192; called by muse, mutect2, varscan2
- AMOTL1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 130/552 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs755948371, COSV100504867; called by muse, mutect2, varscan2
- ANGPTL1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 142/601 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as rs367579998; called by muse, mutect2, varscan2
- ANGPTL8 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs781506138; called by muse, mutect2, varscan2
- ANK1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55871816; called by muse, mutect2, varscan2
- ANK2 | c.3367G>A p.G1123S | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138381417; called by muse, mutect2, varscan2
- ANK3 | c.6778G>A p.G2260S | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs192587828, COSV99778504; called by muse, mutect2, varscan2
- ANKH | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs764910926; called by muse, mutect2, varscan2
- ANKLE1 | c.1465C>T p.Q489* (on ENST00000394458; = p.Q435* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 61/257 reads (24%) | catalogued as rs560635345; called by muse, mutect2, varscan2
- ANKRD11 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 93/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56369004; called by muse, mutect2, varscan2
- ANKRD27 | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs759978285; called by muse, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 88/374 reads (24%) | catalogued as rs1279723268; called by mutect2, varscan2
- ANKRD31 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1399754846; called by muse, mutect2, varscan2
- ANKRD36B | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs369666439; called by muse, mutect2, varscan2
- ANKRD44 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 59/319 reads (18%) | catalogued as rs147529433; called by muse, varscan2
- ANTKMT | c.686dup p.L230Pfs*? | Frame Shift Ins (INS) | VAF 46/187 reads (25%) | catalogued as rs755358433; called by mutect2, varscan2
- AOX1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV65984378; called by mutect2, varscan2
- AP000812.4 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs1372399805, COSV99597694; called by muse, mutect2, varscan2
- AP3D1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372956453; called by muse, mutect2, varscan2
- AQP3 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 76/308 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs756008789; called by muse, mutect2, varscan2
- AQP7 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs780270047, COSV53035946; called by muse, mutect2, varscan2
- ARAP1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs768446677; called by muse, mutect2, varscan2
- ARFGAP3 | c.669del p.G224Afs*32 | Frame Shift Del (DEL) | VAF 40/187 reads (21%) | catalogued as rs1436718702, COSV54312627; called by mutect2, varscan2
- ARFGEF3 | c.5599G>A p.A1867T | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs766044916, COSV52457823; called by muse, mutect2, varscan2
- ARFIP1 | c.922C>T p.R308C (on ENST00000353617 / NM_001287432.1; = p.R276C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/377 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367792760; called by muse, mutect2, varscan2
- ARHGAP25 | c.1846C>T p.R616C (on ENST00000409202 / NM_001007231.3; = p.R608C on NM_014882.3) | Missense Mutation (SNP) | VAF 156/657 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as rs764265797, COSV54903451; called by muse, mutect2, varscan2
- ARHGAP39 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777563207; called by muse, mutect2, varscan2
- ARHGAP44 | c.198C>T p.S66= | Splice Region (SNP) | VAF 37/147 reads (25%) | catalogued as rs202018989; called by muse, mutect2, varscan2
- ARHGEF10 | c.2927C>T p.P976L (on ENST00000398564; = p.P951L on NM_014629.4) | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs776643949, COSV50642258; called by muse, mutect2
- ARHGEF11 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 75/401 reads (19%) | catalogued as COSV63811869; called by muse, mutect2, varscan2
- ARHGEF17 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); catalogued as rs567330760; called by muse, mutect2, varscan2
- ARHGEF18 | c.2860G>A p.E954K (on ENST00000359920 / NM_001130955.2; = p.E850K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs993334421, COSV100150146; called by muse, mutect2, varscan2
- ARL10 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV53798213; called by muse, mutect2, varscan2
- ARNT | c.1783del p.R595Gfs*11 | Frame Shift Del (DEL) | VAF 36/220 reads (16%) | catalogued as COSV62230627; called by mutect2, varscan2
- ASAH2 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 94/479 reads (20%) | catalogued as rs1194660932, COSV61483494; called by muse, mutect2, varscan2
- ASS1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs201445618; called by muse, mutect2, varscan2
- ASTN1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1364819044; called by muse, mutect2, varscan2
- ASTN2 | c.3989G>A p.R1330Q (on ENST00000313400 / NM_001365069.1; = p.R1279Q on NM_014010.5) | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.978); catalogued as rs367824366; called by muse, mutect2, varscan2
- ATG2B | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 102/494 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746956149; called by muse, mutect2, varscan2
- ATG9B | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs1312209539, COSV99871688; called by muse, mutect2, varscan2
- ATG9B | c.2646C>T p.D882= | Splice Region (SNP) | VAF 44/156 reads (28%) | catalogued as rs545593603, COSV99872428; called by muse, varscan2
- ATP5MC2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs781062050, COSV58601745; called by muse, mutect2, varscan2
- ATP8B1 | c.3695C>T p.S1232L | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs778749552, COSV52173063; called by muse, varscan2
- ATXN3L | c.585del p.K195Nfs*2 | Frame Shift Del (DEL) | VAF 116/248 reads (47%) | catalogued as rs1411781059; called by mutect2, varscan2
- AVPI1 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773089599; called by muse, mutect2, varscan2
- AXIN1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145608130; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 56/320 reads (18%) | catalogued as rs778012871; called by mutect2, varscan2
- B3GLCT | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 106/525 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769182025; called by muse, mutect2, varscan2
- B3GNT9 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329819842, COSV54628915; called by muse, mutect2, varscan2
- B4GALT6 | c.55A>T p.I19F | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs773183141; called by muse, mutect2, varscan2
- BAG5 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758744586, COSV99915014; called by muse, mutect2, varscan2
- BCL2L2 | c.463del p.A155Pfs*16 | Frame Shift Del (DEL) | VAF 51/284 reads (18%) | catalogued as COSV99161543; called by mutect2, varscan2
- BEND7 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 138/673 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1184445078; called by muse, varscan2
- BEST2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as rs757587843, COSV50363408; called by muse, mutect2, varscan2
- BICD1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99863162; called by muse, mutect2, varscan2
- BICRA | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1215558782, COSV67604756; called by muse, mutect2, varscan2
- BIRC6 | c.9685C>T p.L3229F | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1216100664; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2734G>A p.V912I | Missense Mutation (SNP) | VAF 114/519 reads (22%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.023); catalogued as rs140135562; called by muse, mutect2, varscan2
- BLNK | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 79/340 reads (23%) | catalogued as rs200501515; called by muse, mutect2, varscan2
- BMERB1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 81/395 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1208487544, COSV100252561; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 103/423 reads (24%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BNC1 | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 117/499 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61757595; called by muse, mutect2, varscan2
- BRAP | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 114/626 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs770298646, COSV59537780; called by muse, mutect2, varscan2
- BRAT1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs745563920, COSV61397659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs1254272998, COSV99350570; called by muse, mutect2, varscan2
- BRD3 | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs774040378, COSV57702822; called by muse, mutect2, varscan2
- BRPF3 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 67/354 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1442029620; called by muse, mutect2, varscan2
- BRSK1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs755357977; called by muse, mutect2, varscan2
- BRSK1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs200690719; called by muse, mutect2, varscan2
- BSCL2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs202072835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771863939; called by muse, mutect2, varscan2
- BTNL9 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs781133085; called by muse, mutect2, varscan2
- C11orf95 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1192269990, COSV58032727; called by muse, varscan2
- C18orf54 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 78/420 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.157); catalogued as rs146934571, COSV100266395; called by muse, varscan2
- C2CD5 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 58/424 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs139822705; called by muse, mutect2, varscan2
- C5 | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 80/379 reads (21%) | catalogued as COSV56325970; called by muse, mutect2, varscan2
- C5orf46 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs375956579; called by muse, mutect2, varscan2
- C6orf132 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1275712359; called by muse, mutect2, varscan2
- C6orf132 | c.920del p.P307Qfs*210 | Frame Shift Del (DEL) | VAF 71/290 reads (24%) | catalogued as COSV59375430; called by mutect2, varscan2
- CACNA1A | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs1353041373; called by muse, mutect2, varscan2
- CACNA1B | c.4703G>A p.R1568H | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99501175; called by muse, mutect2, varscan2
- CACNA1I | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1278074840, COSV60802941; called by muse, mutect2, varscan2
- CACNA1S | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.992); catalogued as rs373701906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781210506, COSV99818083; called by muse, mutect2, varscan2
- CALD1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62646346; called by muse, mutect2, varscan2
- CALHM3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs867022038; called by muse, mutect2, varscan2
- CAMKK2 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1310112012; called by muse, varscan2
- CAMTA1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1470142432, COSV57909520; called by muse, mutect2, varscan2
- CAMTA1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs1181886794; called by muse, mutect2, varscan2
- CAPN10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.26); catalogued as rs770374333; called by muse, mutect2, varscan2
- CAPN10 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.059); catalogued as rs752063033; called by muse, mutect2, varscan2
- CASKIN2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs371781299; called by muse, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 92/458 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs530151570, COSV59740183; called by muse, varscan2
- CASZ1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs146887532; called by muse, mutect2, varscan2
- CCDC102B | c.1259dup p.N420Kfs*13 | Frame Shift Ins (INS) | VAF 48/184 reads (26%) | catalogued as rs562973346; called by mutect2, varscan2
- CCDC105 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 66/309 reads (21%) | catalogued as rs372493151; called by muse, mutect2, varscan2
- CCDC110 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 73/448 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs546423737, COSV56873334; called by muse, mutect2
- CCDC113 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs147141699; called by muse, mutect2, varscan2
- CCDC120 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782072841, COSV64480869; called by muse, mutect2, varscan2
- CCDC15 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs760911695, COSV100776989, COSV61084753; called by muse, mutect2, varscan2
- CCDC166 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV101545877; called by muse, mutect2, varscan2
- CCDC170 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs200841666, COSV53339624; called by muse, mutect2, varscan2
- CCDC180 | c.2196G>T p.E732D | Missense Mutation (SNP) | VAF 88/394 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); catalogued as rs12353275; called by mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 72/264 reads (27%) | catalogued as rs1423532083; called by mutect2, varscan2
- CCDC181 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 113/566 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs187334513; called by muse, mutect2, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 62/280 reads (22%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 30/161 reads (19%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC81 | c.1400C>T p.A467V (on ENST00000445632 / NM_001156474.2; = p.A377V on NM_021827.4) | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs771099705; called by muse, mutect2, varscan2
- CCHCR1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 175/612 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1165145831; called by muse, mutect2, varscan2
- CCHCR1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 83/410 reads (20%) | catalogued as rs767157475, COSV100885732; called by muse, mutect2, varscan2
- CCNJL | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 73/336 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs748396775; called by muse, mutect2, varscan2
- CCR6 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs774906837; called by muse, mutect2, varscan2
- CCR9 | c.430A>G p.R144G (on ENST00000357632 / NM_031200.3; = p.R132G on NM_006641.4) | Missense Mutation (SNP) | VAF 87/414 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748863151; called by muse, mutect2, varscan2
- CD151 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs1019424026; called by muse, mutect2, varscan2
- CD247 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 96/446 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs144963570; called by muse, mutect2, varscan2
- CD40 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754006524, COSV100953780; called by muse, mutect2, varscan2
- CD5L | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs74121552, COSV63823026; called by muse, mutect2, varscan2
- CDC123 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 75/350 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752328200, COSV55395725; called by muse, mutect2, varscan2
- CDC16 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV52958720; called by muse, mutect2, varscan2
- CDC42BPB | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 98/425 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780626139; called by muse, varscan2
- CDH10 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 117/609 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760804087, COSV52572298, COSV52585105; called by muse, mutect2, varscan2
- CDH19 | c.1841del p.L614* | Frame Shift Del (DEL) | VAF 50/208 reads (24%) | catalogued as rs1568168060; called by mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 145/629 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CDHR2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs745929407; called by muse, mutect2, varscan2
- CDHR2 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 58/305 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs746333783, COSV56135002, COSV56137768; called by muse, mutect2, varscan2
- CDK12 | c.4067G>A p.R1356Q (on ENST00000447079 / NM_016507.4; = p.R1347Q on NM_015083.3) | Missense Mutation (SNP) | VAF 108/482 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.273); catalogued as rs761089485, COSV71001791; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4223G>A p.R1408H | Missense Mutation (SNP) | VAF 93/424 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1014026370; called by muse, mutect2, varscan2
- CDK6 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs373488172, COSV56008836; called by muse, mutect2, varscan2
- CDKN3 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 100/408 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1286825216; called by muse, mutect2, varscan2
- CDRT1 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs369935359; called by muse, varscan2
- CEACAM16 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777496967, COSV101312772; called by muse, mutect2, varscan2
- CELF2 | c.1127C>T p.T376M (on ENST00000416382 / NM_001025077.3; = p.T389M on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV100258199; called by muse, mutect2, varscan2
- CELSR2 | c.5410G>A p.A1804T | Missense Mutation (SNP) | VAF 98/373 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs770840359; called by muse, mutect2, varscan2
- CEMIP2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 144/632 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as rs778331613, COSV100987406; called by muse, mutect2, varscan2
- CENPF | c.8509G>A p.D2837N | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs138734779; called by muse, mutect2, varscan2
- CENPQ | c.125del p.N42Ifs*5 | Frame Shift Del (DEL) | VAF 56/248 reads (23%) | catalogued as rs756590976; called by mutect2, varscan2
- CEP170B | c.723del p.E242Rfs*41 (on ENST00000453495; = p.E171Rfs*41 on NM_015005.3) | Frame Shift Del (DEL) | VAF 49/244 reads (20%) | catalogued as COSV69024902; called by mutect2, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 64/242 reads (26%) | catalogued as COSV58068098; called by mutect2, varscan2
- CEP350 | c.6232del p.R2078Gfs*6 | Frame Shift Del (DEL) | VAF 130/532 reads (24%) | catalogued as rs759430139; called by mutect2, varscan2
- CEP95 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 91/458 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs782398984; called by muse, mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 28/153 reads (18%) | catalogued as rs747835123, COSV61504174; called by mutect2, varscan2
- CFAP46 | c.7358C>T p.A2453V | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs768215654; called by muse, mutect2, varscan2
- CFAP61 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 104/535 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs567725378; called by muse, mutect2, varscan2
- CGB3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs1462326318; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 84/390 reads (22%) | catalogued as rs1561489348; called by mutect2, varscan2
- CHD2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 112/510 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100560575; called by muse, mutect2, varscan2
- CHD4 | c.3244C>T p.R1082C (on ENST00000357008 / NM_001363606.2; = p.R1095C on NM_001273.5) | Missense Mutation (SNP) | VAF 136/511 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100538432; called by muse, mutect2, varscan2
- CHD7 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 106/491 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as rs765180149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.6080G>T p.R2027L | Missense Mutation (SNP) | VAF 114/455 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV71112607; called by mutect2, varscan2
- CHFR | c.833G>A p.R278H (on ENST00000432561 / NM_001161345.1; = p.R237H on NM_018223.2) | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs375174098; called by muse, mutect2, varscan2
- CHFR | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746187833; called by muse, mutect2, varscan2
- CHID1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs777138598; called by muse, mutect2, varscan2
- CHRNB2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs796052326, COSV100872517; ClinVar: uncertain significance; called by muse, varscan2
- CHST1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57322988; called by muse, mutect2, varscan2
- CHST8 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs759507836; called by muse, mutect2, varscan2
- CIAO1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs772533972; called by muse, mutect2, varscan2
- CIITA | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs199476070; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CIP2A | c.2422del p.T808Qfs*29 | Frame Shift Del (DEL) | VAF 25/179 reads (14%) | catalogued as COSV99843074; called by mutect2, varscan2
- CISD2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs868634687; called by muse, mutect2, varscan2
- CLASP1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1472982745, COSV55336545; called by muse, mutect2, varscan2
- CLASRP | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT tolerated (0.08); catalogued as rs780663630; called by muse, mutect2
- CLCN7 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1400598641, COSV99246906; called by muse, mutect2, varscan2
- CLIP2 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.179); catalogued as rs782545372, COSV56281635; called by muse, mutect2, varscan2
- CLIP3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV62112754; called by muse, mutect2, varscan2
- CLK3 | c.712C>T p.R238C (on ENST00000395066 / NM_001130028.1; = p.R90C on NM_003992.4) | Missense Mutation (SNP) | VAF 81/326 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs767369515; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 58/240 reads (24%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPTM1L | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 108/469 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1019362368; called by muse, mutect2, varscan2
- CLSTN1 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363487449; called by muse, mutect2, varscan2
- CMTR1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 46/227 reads (20%) | catalogued as rs747046392; called by muse, mutect2, varscan2
- CNBD1 | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73074582; called by muse, mutect2, varscan2
- CNOT6L | c.538C>T p.R180* (on ENST00000504123 / NM_001286790.2; = p.R175* on NM_144571.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/553 reads (20%) | catalogued as COSV53701253; called by muse, mutect2, varscan2
- CNR1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV62986486; called by muse, mutect2, varscan2
- COL11A2 | c.4482G>A p.P1494= (on ENST00000341947 / NM_080680.3; = p.P1387= on NM_080679.2) | Splice Region (SNP) | VAF 80/387 reads (21%) | catalogued as rs142586242, COSV59503302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128683, COSV65422174; called by muse, mutect2, varscan2
- COL5A1 | c.4121C>T p.T1374M | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs151115748; ClinVar: uncertain significance; called by muse, varscan2
- COL5A1 | c.4909C>T p.R1637C | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753433375, COSV100880383, COSV65669482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs375452881; called by muse, mutect2, varscan2
- COL6A6 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.353); catalogued as rs764994836, COSV62023950; called by muse, mutect2, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 40/232 reads (17%) | catalogued as rs941174282; called by mutect2, varscan2
- COPA | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 124/575 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253097566, COSV54107149; called by muse, mutect2, varscan2
- COPG1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 74/357 reads (21%) | catalogued as rs775727605, COSV59116628; called by muse, mutect2, varscan2
- COPRS | c.90del p.S31Afs*25 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs1567771049; called by mutect2, varscan2
- CORIN | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750996817, COSV56686834; called by muse, mutect2, varscan2
- CORIN | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 97/405 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV99904277; called by muse, mutect2, varscan2
- CPNE5 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs778477100; called by muse, mutect2, varscan2
- CPNE8 | c.285del p.F95Lfs*41 | Frame Shift Del (DEL) | VAF 42/196 reads (21%) | catalogued as COSV58849117; called by mutect2, varscan2
- CPT1A | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139057953; called by muse, mutect2, varscan2
- CR1 | c.5230C>T p.R1744* | Nonsense Mutation (SNP) | VAF 20/220 reads (9%) | catalogued as rs55749440, COSV65457864; called by muse, mutect2
- CR2 | c.2503A>G p.T835A | Missense Mutation (SNP) | VAF 83/461 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as rs1367099391; called by muse, mutect2, varscan2
- CRAT | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs760770816, COSV100540034; called by muse, mutect2, varscan2
- CRB1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 108/516 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as CM040711, COSV66329127, COSV66331096; called by muse, mutect2, varscan2
- CRB2 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs755802369; called by muse, mutect2, varscan2
- CRTC2 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1433609577; called by muse, mutect2, varscan2
- CSF1R | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs372068592; called by muse, mutect2, varscan2
- CSF3R | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779227407, COSV58966490; called by muse, mutect2, varscan2
- CSMD2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759408814; called by muse, mutect2, varscan2
- CSMD2 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53882610; called by muse, mutect2, varscan2
- CSNK1E | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.614); catalogued as rs759550035; called by muse, varscan2
- CSPG4 | c.6739C>T p.R2247* | Nonsense Mutation (SNP) | VAF 44/216 reads (20%) | catalogued as rs777249049, COSV57889753; called by muse, mutect2, varscan2
- CST6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1411186911; called by muse, mutect2, varscan2
- CTNNA2 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 83/429 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as rs752704214, COSV63547968; called by muse, mutect2, varscan2
- CTNNAL1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1250786842; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 74/390 reads (19%) | catalogued as rs761516328; called by mutect2, varscan2
- CTNNBL1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757144734; called by muse, mutect2, varscan2
- CTNND1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); catalogued as rs754613241, COSV62382631; called by muse, mutect2, varscan2
- CTSV | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 89/444 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs372363372; called by muse, mutect2, varscan2
- CTTN | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs267603163; called by muse, mutect2, varscan2
- CWC22 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 133/634 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs373594028; called by muse, mutect2, varscan2
- CWC27 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 98/500 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765721927; called by muse, mutect2, varscan2
- CYB5R1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 97/445 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs755233575, COSV100924852; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 116/260 reads (45%) | catalogued as rs745836350; called by mutect2, varscan2
- CYFIP1 | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs769699388; called by muse, mutect2, varscan2
- CYHR1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as COSV71324651; called by muse, mutect2, varscan2
- CYP1B1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as CM066030; called by muse, mutect2, varscan2
- CYP46A1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.978); catalogued as rs756141971; called by muse, mutect2, varscan2
- CYTH2 | c.960G>A p.P320= (on ENST00000427476; = p.P319= on NM_004228.7) | Splice Region (SNP) | VAF 41/195 reads (21%) | catalogued as rs766860687, COSV57309254; called by muse, varscan2
- DAPK1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs370724837; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 62/294 reads (21%) | catalogued as rs779681511; called by mutect2, varscan2
- DAZAP1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as rs1053723670, COSV99245627; called by muse, mutect2, varscan2
- DBF4B | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 87/376 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs774163525; called by muse, mutect2, varscan2
- DCAF1 | c.3008C>T p.T1003M | Missense Mutation (SNP) | VAF 108/502 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs782486639; called by muse, varscan2
- DCAF12L2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV63583920; called by muse, mutect2, varscan2
- DCAF5 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 109/420 reads (26%) | catalogued as COSV58458695; called by muse, mutect2, varscan2
- DCHS1 | c.7756G>A p.V2586M | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs747141130, COSV54996502; called by muse, mutect2, varscan2
- DCHS1 | c.5431C>T p.R1811W | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757316767, COSV55044575; called by muse, mutect2, varscan2
- DCXR | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs752090622; called by muse, varscan2
- DDN | c.1411dup p.R471Pfs*31 | Frame Shift Ins (INS) | VAF 58/251 reads (23%) | catalogued as rs773412144; called by mutect2, varscan2
- DDRGK1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753666292, COSV100621543; called by muse, varscan2
- DDX11 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs751955009, COSV99299994; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 128/602 reads (21%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 60/225 reads (27%) | catalogued as rs757771764; called by mutect2, varscan2
- DENND1A | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs754417395; called by muse, mutect2, varscan2
- DENND4A | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 104/539 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1248901572; called by muse, mutect2, varscan2
- DES | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406795636; called by muse, mutect2, varscan2
- DESI2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 91/394 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.236); catalogued as rs373776959; called by muse, mutect2, varscan2
- DHX16 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1273530977, COSV64579712; called by muse, mutect2, varscan2
- DHX57 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs772689230, COSV54892254; called by muse, mutect2, varscan2
- DHX9 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 87/380 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV62359156; called by muse, mutect2, varscan2
- DIAPH3 | c.2581G>A p.G861R (on ENST00000400324 / NM_001042517.2; = p.G598R on NM_030932.3) | Missense Mutation (SNP) | VAF 91/371 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368347883; called by muse, mutect2, varscan2
- DIP2C | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1485067164; called by muse, mutect2, varscan2
- DIPK1B | c.400del p.R134Gfs*22 | Frame Shift Del (DEL) | VAF 42/222 reads (19%) | catalogued as COSV63038346; called by mutect2, varscan2
- DIPK2B | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 11/378 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs945106817, COSV65005746, COSV65005879; called by muse, mutect2
- DLEC1 | c.4387G>A p.V1463M | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199537711; called by muse, mutect2, varscan2
- DLG1 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs560145346; called by muse, mutect2, varscan2
- DLGAP5 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 92/433 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs766110350; called by muse, mutect2, varscan2
- DMAC2 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148395303; called by muse, mutect2, varscan2
- DMBX1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 60/347 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100760721; called by muse, mutect2, varscan2
- DNAH12 | c.6362G>A p.R2121H (on ENST00000351747; = p.R2140H on NM_001366028.2) | Missense Mutation (SNP) | VAF 103/492 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969549110, COSV61054794; called by muse, mutect2, varscan2
- DNAH17 | c.8891C>T p.A2964V | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760238543, COSV67756311; called by muse, mutect2, varscan2
- DNAH3 | c.4760G>A p.R1587H | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765153588; called by muse, mutect2, varscan2
- DNAH5 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774191944, COSV54217609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC16 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777085250; called by muse, mutect2, varscan2
- DNHD1 | c.6187G>A p.G2063S | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757027777; called by muse, varscan2
- DNMT3A | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as rs1183198167, COSV53038083, COSV53044768; called by muse, varscan2
- DOCK4 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 109/418 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202096330; called by muse, mutect2, varscan2
- DOHH | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs778229924, COSV51744035; called by muse, mutect2, varscan2
- DPH7 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 85/417 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs922412367; called by muse, mutect2, varscan2
- DPP9 | c.2531G>A p.C844Y (on ENST00000598800; = p.C873Y on NM_139159.5) | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.484); catalogued as rs981667065; called by muse, mutect2, varscan2
- DSCAM | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 83/411 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1227425619, COSV68021037; called by muse, mutect2, varscan2
- DSCAML1 | c.3473G>A p.R1158Q (on ENST00000321322; = p.R1098Q on NM_020693.4) | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.726); catalogued as rs953338496; called by muse, varscan2
- DSCAML1 | c.2627G>A p.R876Q (on ENST00000321322; = p.R816Q on NM_020693.4) | Missense Mutation (SNP) | VAF 55/312 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); catalogued as rs1028890107, COSV58382762; called by muse, mutect2, varscan2
- DST | c.3280C>A p.L1094M (on ENST00000361203 / NM_001374722.1; = p.L768M on NM_001723.6) | Missense Mutation (SNP) | VAF 121/621 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs756379041, COSV55031525; called by muse, mutect2, varscan2
- DTNA | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774480677, COSV99313992; called by muse, mutect2, varscan2
- DUSP8 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 92/420 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as rs762548136; called by muse, mutect2, varscan2
- DVL1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.83); catalogued as rs1254209708, COSV66678109; called by muse, mutect2, varscan2
- DYNC1H1 | c.10631G>A p.R3544H | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761216533, COSV64137354; called by muse, mutect2, varscan2
- DYNC1H1 | c.11389G>A p.V3797M | Missense Mutation (SNP) | VAF 89/399 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760876077, COSV100795447; called by muse, mutect2, varscan2
- DYTN | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV71752718; called by muse, mutect2, varscan2
- ECE1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1295873616; called by muse, mutect2, varscan2
- EEF2K | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 84/393 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53784849; called by muse, mutect2, varscan2
- EFCAB9 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1356894091; called by muse, mutect2, varscan2
- EFEMP2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 118/400 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779247685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFNA2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); catalogued as rs757316290, COSV53065375; called by muse, mutect2, varscan2
- ELANE | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.218); catalogued as rs1396230082, CM104210, COSV52256451; called by muse, mutect2, varscan2
- ELMOD2 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 119/568 reads (21%) | catalogued as rs750143144; called by muse, mutect2, varscan2
- ELOA | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs775582884; called by muse, mutect2, varscan2
- EMC1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748974716, COSV61887025; called by muse, mutect2, varscan2
- EMILIN1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs201575918, COSV66695118; called by muse, mutect2, varscan2
- ENOX1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 107/535 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs764001017, COSV54894322; called by muse, mutect2, varscan2
- EPHB2 | c.2191G>A p.A731T (on ENST00000400191 / NM_001309193.2; = p.A732T on NM_004442.7) | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs142161660; called by muse, varscan2
- EPHB2 | c.3120del p.F1040Lfs*43 | Frame Shift Del (DEL) | VAF 90/400 reads (23%) | catalogued as rs770822649; called by mutect2, varscan2
- EPHX1 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs763600235; called by muse, varscan2
- EPM2AIP1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV51621142; called by muse, mutect2, varscan2
- EPN1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs774551624; called by muse, mutect2, varscan2
- EPN2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs951398293, COSV59061029; called by muse, mutect2, varscan2
- ERN1 | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 89/380 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs200358341; called by muse, mutect2, varscan2
- ERN1 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs780870849, COSV70500856; called by muse, mutect2, varscan2
- ERN1 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs370673725; called by muse, mutect2, varscan2
- ESPNL | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs759308208, COSV54540000; called by muse, mutect2, varscan2
- ESRP1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 96/356 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64410745; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 96/384 reads (25%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 96/430 reads (22%) | catalogued as rs765136869; called by mutect2, varscan2
- EVX2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs760847501; called by muse, varscan2
- EXO5 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs781656662; called by muse, mutect2, varscan2
- EXTL3 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 96/423 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as rs139633425, COSV55038590; called by muse, varscan2
- EYS | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 91/441 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs760342117; called by muse, mutect2, varscan2
- FAM133B | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as rs772730489; called by muse, mutect2, varscan2
- FAM13B | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 57/250 reads (23%) | catalogued as rs756297490, COSV50365444; called by muse, mutect2, varscan2
- FAM168A | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs568533341; called by muse, mutect2, varscan2
- FAM170B | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs1196785528, COSV100308476; called by muse, mutect2, varscan2
- FAM171A1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs574266280; called by muse, mutect2, varscan2
- FAM189A1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 80/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768291963; called by muse, varscan2
- FAM189B | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as rs911612235; called by muse, mutect2, varscan2
- FAM71A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 89/471 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs777022954, COSV54235101, COSV54236851; called by muse, mutect2, varscan2
- FAM83C | c.2231G>A p.R744H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs561188076, COSV65583802; called by muse, mutect2, varscan2
- FAM90A1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs751330423, COSV56711564; called by muse, mutect2, varscan2
- FAM98C | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768768718; called by muse, mutect2, varscan2
- FANCE | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as rs377415237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.6487C>T p.R2163C | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031448244; called by muse, mutect2, varscan2
- FAT1 | c.11737G>A p.A3913T | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs773650405, COSV101499198; called by muse, mutect2, varscan2
- FAT2 | c.9610G>A p.V3204I | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs140898888; called by muse, mutect2, varscan2
- FAT3 | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.083); catalogued as rs774983511, COSV53121160; called by muse, mutect2, varscan2
- FBF1 | c.2870G>A p.R957Q (on ENST00000586717; = p.R972Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs553617516; called by muse, mutect2, varscan2
- FBN2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs863223559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL18 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs775995098, COSV66665310, COSV66668783; called by muse, mutect2, varscan2
- FBXO24 | c.1465C>T p.R489C (on ENST00000241071 / NM_033506.3; = p.R527C on NM_012172.5) | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs762948451, COSV53828731; called by muse, mutect2, varscan2
- FBXO41 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs879431027; called by muse, mutect2, varscan2
- FBXW11 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as rs773518789, COSV51612643; called by muse, mutect2, varscan2
- FGD2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779897171; called by muse, mutect2, varscan2
- FGD3 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770049768; called by muse, mutect2, varscan2
- FGD4 | c.2046C>T p.D682= | Splice Region (SNP) | VAF 64/296 reads (22%) | catalogued as rs371833051, COSV56786822; called by muse, mutect2
- FGF8 | c.623G>A p.R208H (on ENST00000344255 / NM_033164.4; = p.R190H on NM_006119.6) | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs769174862; called by muse, mutect2, varscan2
- FGFR4 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs778723081, COSV52804574, COSV52807189; called by muse, mutect2, varscan2
- FILIP1 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 61/265 reads (23%) | catalogued as rs752395530, COSV52723288, COSV52733745; called by muse, mutect2, varscan2
- FILIP1L | c.1034G>A p.R345Q (on ENST00000354552 / NM_182909.3; = p.R105Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/505 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.13); catalogued as rs374961168; called by muse, mutect2, varscan2
- FIZ1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1028650315; called by muse, mutect2
- FKRP | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1276654268; called by muse, mutect2, varscan2
- FLG | c.6776G>A p.R2259Q | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs542918091, COSV64246345; called by muse, mutect2
- FLG | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs757922040, COSV100911849; called by muse, varscan2
- FLT4 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99986624; called by muse, mutect2, varscan2
- FMN2 | c.2848G>A p.G950R | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.822); catalogued as rs1276801853; called by muse, mutect2, varscan2
- FN1 | c.5741C>T p.T1914I | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs756331026; called by muse, mutect2, varscan2
- FN1 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 109/440 reads (25%) | catalogued as COSV60564371; called by muse, mutect2, varscan2
- FNDC11 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs779082342; called by muse, mutect2, varscan2
- FNDC11 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs752740200, COSV64442580; called by muse, varscan2
- FNDC3B | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560089040; called by muse, mutect2, varscan2
- FNDC4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 76/454 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1356804969; called by muse, mutect2, varscan2
- FOXF1 | c.1085del p.G362Afs*17 | Frame Shift Del (DEL) | VAF 46/276 reads (17%) | catalogued as COSV52287150; called by mutect2, varscan2
- FOXI1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as rs371742098, COSV100089553; called by muse, mutect2, varscan2
- FOXN3 | c.1237G>A p.G413R (on ENST00000261302; = p.G391R on NM_005197.4) | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs201853361; called by muse, mutect2, varscan2
- FRA10AC1 | c.76del p.R26Gfs*44 | Frame Shift Del (DEL) | VAF 58/260 reads (22%) | catalogued as rs755202796; called by mutect2, varscan2
- FRAS1 | c.6376C>T p.R2126C | Missense Mutation (SNP) | VAF 90/476 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs779986441; called by muse, varscan2
- FRAT2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs909251895; called by muse, mutect2, varscan2
- FREM3 | c.2392C>T p.R798W | Missense Mutation (SNP) | VAF 100/480 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs776491489; called by muse, mutect2, varscan2
- FTCD | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144080295, COSV52423529; called by muse, varscan2
- FUT11 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 85/437 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs1191668812; called by muse, varscan2
- FUT4 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1217770182, COSV100707974; called by muse, mutect2, varscan2
- FYCO1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs773743760; called by muse, mutect2, varscan2
- FZD7 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 81/318 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV53808675; called by muse, mutect2, varscan2
- FZR1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1293528826, COSV58053277; called by muse, mutect2, varscan2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 58/282 reads (21%) | catalogued as rs777471402; called by mutect2, varscan2
- GABBR1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 166/721 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100589754; called by muse, mutect2, varscan2
- GABBR2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs978945843, COSV52309784; called by muse, mutect2, varscan2
- GABRB2 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs777778428, COSV50905153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | catalogued as rs1553309006; called by mutect2, varscan2
- GAREM1 | c.2462G>A p.R821Q (on ENST00000269209 / NM_001242409.2; = p.R820Q on NM_022751.3) | Missense Mutation (SNP) | VAF 101/436 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs756156267; called by muse, mutect2, varscan2
- GAS2L2 | c.2433del p.K812Rfs*5 | Frame Shift Del (DEL) | VAF 56/268 reads (21%) | catalogued as rs782288149; called by mutect2, varscan2
- GATA4 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1245034279, COSV100633118; called by muse, mutect2, varscan2
- GATAD1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs564747350, COSV99843623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATAD2A | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.391); catalogued as rs760258128; called by muse, mutect2, varscan2
- GCN1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs750521946, COSV100325005; called by muse, mutect2, varscan2
- GEMIN5 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs371819928; called by muse, mutect2, varscan2
- GFRA1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1005537154, COSV100815894, COSV62602441; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 46/170 reads (27%) | catalogued as rs750227570; called by mutect2, varscan2
- GLB1L2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746777635; called by muse, mutect2, varscan2
- GLI2 | c.2384C>T p.T795M (on ENST00000361492 / NM_001374353.1; = p.T812M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773308985, COSV58052651; called by muse, mutect2, varscan2
- GLOD4 | c.250G>A p.A84T (on ENST00000301328 / NM_001366247.1; = p.A69T on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 168/743 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs756805516; called by muse, mutect2, varscan2
- GLRB | c.752-1G>T p.X251_splice | Splice Site (SNP) | VAF 53/222 reads (24%) | catalogued as COSV52420477; called by muse, mutect2, varscan2
- GNAI2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782805532; called by muse, mutect2, varscan2
- GNL3 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs372615484; called by muse, mutect2, varscan2
- GPR101 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs144604669, COSV53239022; called by muse, mutect2, varscan2
- GPR12 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67344032; called by muse, mutect2, varscan2
- GPR135 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67749879; called by muse, mutect2, varscan2
- GPR174 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 171/341 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs200548821, CM136727; called by muse, mutect2, varscan2
- GPR62 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59055832; called by muse, mutect2, varscan2
- GPR68 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1343501010, COSV53176819; called by muse, varscan2
- GPR89A | c.337dup p.S113Ffs*71 | Frame Shift Ins (INS) | VAF 18/94 reads (19%) | catalogued as rs1256102621; called by mutect2, varscan2
- GPRC5B | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs530209030; called by muse, mutect2, varscan2
- GPRIN2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 48/572 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs781936680; called by muse, mutect2
- GRHPR | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs774233908, COSV58944706; called by muse, mutect2, varscan2
- GRID1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 75/439 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs760195348, COSV60025408; called by muse, mutect2, varscan2
- GRIN3B | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1369396143; called by muse, mutect2, varscan2
- GRM1 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 106/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746660819, COSV51174083; called by muse, mutect2, varscan2
- GRM5 | c.3497C>T p.P1166L (on ENST00000305447 / NM_001143831.2; = p.P1134L on NM_000842.4) | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs1317020135; called by muse, mutect2, varscan2
- GRXCR2 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 117/567 reads (21%) | catalogued as rs762841261; called by muse, mutect2, varscan2
- GSG1L | c.898C>T p.R300* (on ENST00000447459 / NM_001109763.2; = p.R145* on NM_144675.2) | Nonsense Mutation (SNP) | VAF 47/223 reads (21%) | catalogued as rs763637151, COSV101093691, COSV66580614; called by muse, mutect2, varscan2
- GTF2I | c.566del p.L189* | Frame Shift Del (DEL) | VAF 69/385 reads (18%) | catalogued as COSV60399209; called by mutect2, varscan2
- GTF2IRD2B | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as rs782552756; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs202112649; called by muse, mutect2, varscan2
- GTF3C1 | c.1907+1G>A p.X636_splice | Splice Site (SNP) | VAF 74/286 reads (26%) | catalogued as COSV62240602; called by muse, mutect2, varscan2
- GUCY2C | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376847075; called by muse, mutect2, varscan2
- GYPC | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs149400883; called by muse, mutect2, varscan2
- H4C9 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100574868; called by muse, mutect2, varscan2
- HAPLN3 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773603379; called by muse, mutect2, varscan2
- HAPLN3 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 71/337 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199664746, COSV62084501; called by muse, mutect2, varscan2
- HAS1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV55787516; called by muse, mutect2, varscan2
- HAS3 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs746052927, COSV54706161; called by muse, mutect2, varscan2
- HCK | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757866724, COSV99393939, COSV99394128; called by muse, mutect2, varscan2
- HCN1 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 93/400 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV57518436; called by muse, mutect2, varscan2
- HCN3 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1481497043; called by muse, mutect2, varscan2
- HCRTR2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 133/501 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV63796162; called by muse, mutect2, varscan2
- HDGFL1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1184843939, COSV57751246; called by muse, varscan2
- HEATR5A | c.5386C>T p.R1796W | Missense Mutation (SNP) | VAF 102/495 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs372690763; called by muse, mutect2, varscan2
- HECTD4 | c.11486C>T p.T3829M | Missense Mutation (SNP) | VAF 72/350 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746255951, COSV66395002; called by muse, mutect2, varscan2
- HECTD4 | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1208722334; called by muse, mutect2, varscan2
- HECW1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs532143087, COSV67829190; called by muse, mutect2, varscan2
- HEG1 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 119/499 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1187475335; called by muse, mutect2, varscan2
- HELZ2 | c.6271G>A p.V2091I (on ENST00000467148 / NM_001037335.2; = p.V1522I on NM_033405.3) | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1024311463, COSV71296137; called by muse, varscan2
- HEMGN | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 118/570 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52325922; called by muse, mutect2, varscan2
- HERC1 | c.12728del p.K4243Rfs*12 | Frame Shift Del (DEL) | VAF 118/448 reads (26%) | catalogued as rs1487761198; called by mutect2, varscan2
- HERC1 | c.12001T>G p.L4001V | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.397); catalogued as rs1177171990; called by muse, mutect2, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 78/388 reads (20%) | catalogued as rs1256699530; called by mutect2, varscan2
- HERC6 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs371365965; called by muse, mutect2, varscan2
- HEXD | c.1196G>A p.R399H (on ENST00000327949 / NM_001369487.1; = p.A429T on NM_173620.3) | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760603638, COSV60062772; called by muse, mutect2, varscan2
- HEYL | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs778733690, COSV65722022; called by muse, mutect2, varscan2
- HGF | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.034); catalogued as COSV55948803; called by muse, mutect2, varscan2
- HHLA1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs118152489; called by muse, mutect2, varscan2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 124/581 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HIF1A | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 148/700 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1251468432, COSV60189211, COSV60191098; called by muse, mutect2, varscan2
- HIP1R | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1476901365; called by muse, varscan2
- HKDC1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs140372000; called by muse, mutect2, varscan2
- HMCN1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 87/345 reads (25%) | catalogued as rs776450081, COSV54876415; called by muse, mutect2, varscan2
- HMCN1 | c.6250G>A p.V2084M | Missense Mutation (SNP) | VAF 90/389 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs577324065, COSV54933716; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 57/260 reads (22%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPM | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs770127136, COSV99725821; called by muse, mutect2, varscan2
- HOXB3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1165198439; called by muse, mutect2, varscan2
- HPS4 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs772234990, COSV61103406; called by muse, mutect2, varscan2
- HSDL1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771834957, COSV99550291; called by muse, mutect2, varscan2
- HSPG2 | c.10862T>C p.L3621P | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs1315174937; called by muse, mutect2, varscan2
- HSPG2 | c.5656C>T p.R1886C | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs566129415, COSV65969378; called by muse, mutect2, varscan2
- HTT | c.5827G>A p.V1943I | Missense Mutation (SNP) | VAF 114/562 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201639415, COSV100750329; called by muse, mutect2, varscan2
- HYDIN | c.7081C>T p.R2361W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs755200815; called by mutect2, varscan2
- IFNL3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs146276429, COSV69829889; called by muse, mutect2, varscan2
- IGF1R | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 102/459 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs773205989; called by muse, mutect2, varscan2
- IGHMBP2 | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs747465472, COSV99661657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGKV2D-26 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1171015961; called by muse, mutect2, varscan2
- IGSF22 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs372284868; called by muse, mutect2, varscan2
- IKZF1 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58792511; called by muse, mutect2, varscan2
- IL17RA | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746356951; called by muse, mutect2, varscan2
- IL17RC | c.1099G>A p.A367T (on ENST00000295981 / NM_153461.4; = p.A281T on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776089912, COSV55974769; called by muse, mutect2, varscan2
- IL17RE | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs992398278; called by muse, mutect2, varscan2
- IL25 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs767350854, COSV59306867; called by muse, mutect2, varscan2
- IL5 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as rs201223432, COSV51504888; called by muse, mutect2, varscan2
- IL6ST | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763726030; called by muse, mutect2, varscan2
- INCENP | c.2233C>T p.R745W (on ENST00000394818 / NM_001040694.2; = p.R741W on NM_020238.3) | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs550675425, COSV53917435; called by muse, mutect2, varscan2
- INHBA | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 125/590 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749750926; called by muse, mutect2, varscan2
- INPP4B | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 52/308 reads (17%) | catalogued as rs1330358087, COSV99526997; called by muse, mutect2, varscan2
- INTS5 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs778593558; called by muse, mutect2, varscan2
- INTU | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs758939107, COSV58871580; called by muse, mutect2, varscan2
- INVS | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 87/359 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752692382, COSV104389905; called by muse, mutect2, varscan2
- IPO13 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1339860243, COSV64893732; called by muse, mutect2, varscan2
- IQSEC3 | c.1462G>A p.V488I (on ENST00000538872 / NM_001170738.2; = p.V185I on NM_015232.1) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV58284848; called by muse, mutect2, varscan2
- IRAG1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 79/388 reads (20%) | catalogued as rs774988512, COSV101350891, COSV70212604; called by muse, mutect2, varscan2
- IRGQ | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV60670227; called by muse, mutect2, varscan2
- IRS1 | c.2576C>T p.T859M | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756434990, COSV59340025; called by muse, mutect2, varscan2
- IRX2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100121697; called by muse, mutect2, varscan2
- ISLR2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1395632632, COSV100679355; called by muse, mutect2, varscan2
- ITGAD | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs369360258; called by muse, mutect2, varscan2
- ITGAD | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201870715; called by muse, mutect2, varscan2
- ITIH2 | c.337G>T p.G113* | Nonsense Mutation (SNP) | VAF 78/390 reads (20%) | catalogued as COSV64432284, COSV64435241; called by muse, mutect2, varscan2
- ITPR2 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781558920; called by muse, varscan2
- ITPR2 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 118/536 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs535598972, COSV67277748; called by muse, mutect2, varscan2
- ITPR3 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs778240357, COSV65415980; called by muse, mutect2, varscan2
- ITSN1 | c.147del p.Q50Nfs*9 | Frame Shift Del (DEL) | VAF 70/242 reads (29%) | catalogued as rs746959118; called by mutect2, varscan2
- ITSN1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs779207769; called by muse, mutect2, varscan2
- JPT1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 88/389 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1396407786, COSV59173228; called by muse, mutect2, varscan2
- KAT2A | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs782071302; called by muse, mutect2, varscan2
- KAT6B | c.6154G>A p.G2052R | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs756847080; called by muse, mutect2, varscan2
- KAZN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755820319, COSV63210399; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 94/372 reads (25%) | catalogued as rs1258313537; called by mutect2, varscan2
- KCNA6 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.057); catalogued as rs778896791; called by muse, mutect2, varscan2
- KCNB2 | c.128del p.G43Afs*40 | Frame Shift Del (DEL) | VAF 46/254 reads (18%) | catalogued as COSV73053085; called by mutect2, varscan2
- KCNC1 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1305576844, COSV56394680; called by muse, mutect2, varscan2
- KCND3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 105/440 reads (24%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.039); catalogued as rs774713377, COSV56175352; called by muse, mutect2, varscan2
- KCNF1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV54462706; called by muse, mutect2, varscan2
- KCNG3 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 124/590 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370971617, COSV100045291; called by muse, mutect2, varscan2
- KCNJ14 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1156545913, COSV60738453, COSV60738556; called by muse, varscan2
- KCNK9 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs754394784, COSV100270392; called by muse, varscan2
- KCNQ5 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs1562230186, COSV59658525; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 67/374 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- KCNT1 | c.1660C>T p.R554C (on ENST00000488444; = p.R573C on NM_020822.3) | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs557219607, COSV53706654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNV1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 106/443 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs1157202808, COSV52084721; called by muse, mutect2, varscan2
- KCNV2 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs766187569, COSV101172463, COSV66056982; called by muse, mutect2, varscan2
- KCTD12 | c.125del p.G42Afs*5 | Frame Shift Del (DEL) | VAF 34/240 reads (14%) | catalogued as COSV58524529; called by mutect2, varscan2
- KDM2A | c.2500del p.R834Vfs*3 | Frame Shift Del (DEL) | VAF 61/307 reads (20%) | catalogued as COSV58189826; called by mutect2, varscan2
- KDM4C | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs776351428, COSV67187037; called by muse, mutect2, varscan2
- KHDRBS3 | c.948C>T p.Y316= | Splice Region (SNP) | VAF 130/555 reads (23%) | catalogued as rs373585149; called by muse, mutect2, varscan2
- KIAA1217 | c.1487del p.P496Lfs*26 | Frame Shift Del (DEL) | VAF 68/324 reads (21%) | catalogued as COSV56813511; called by mutect2, varscan2
- KIAA1522 | c.2705G>A p.R902Q (on ENST00000373480 / NM_001198972.2; = p.R961Q on NM_020888.3) | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.957); catalogued as rs374716724; called by muse, varscan2
- KIF18B | c.1471G>A p.V491M (on ENST00000593135 / NM_001265577.2; = p.V503M on NM_001264573.2) | Missense Mutation (SNP) | VAF 76/372 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs769795016, COSV59274303; called by muse, varscan2
- KIFC1 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 113/516 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs201396332, COSV65729182; called by muse, mutect2, varscan2
- KIRREL1 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474957010; called by muse, mutect2, varscan2
- KIRREL2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 82/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767203597, COSV52875861; called by muse, varscan2
- KISS1R | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs757918057; called by muse, mutect2, varscan2
- KLC2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs771453461; called by muse, mutect2, varscan2
- KLF7 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs747043061; called by muse, mutect2, varscan2
- KLHL41 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 100/459 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99500286; called by muse, mutect2, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 56/246 reads (23%) | catalogued as rs34078597; called by mutect2, varscan2
- KMT2C | c.11590C>T p.R3864C | Missense Mutation (SNP) | VAF 102/603 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs144222590; called by muse, mutect2, varscan2
- KMT2D | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 110/496 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.47); catalogued as rs777682865, COSV56473406; called by muse, mutect2, varscan2
- KPNA3 | c.771+1G>A p.X257_splice | Splice Site (SNP) | VAF 47/308 reads (15%) | catalogued as COSV55507483; called by muse, mutect2, varscan2
- KRT13 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 96/432 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs145116138; called by muse, mutect2, varscan2
- KRT222 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 111/519 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs751191563, COSV67498703; called by muse, mutect2, varscan2
- KRT3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 94/405 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs772879943, COSV58814764; called by muse, mutect2, varscan2
- KRT72 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs368767777, COSV53374553; called by muse, mutect2, varscan2
- KRT79 | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1368877804; called by muse, mutect2, varscan2
- KRT80 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 83/362 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs764141245, COSV100502545; called by muse, mutect2, varscan2
- KSR1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs776835480, COSV99259102; called by muse, mutect2, varscan2
- L1CAM | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 104/194 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs782070899, COSV62828384; called by muse, mutect2, varscan2
- L3MBTL3 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 107/452 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs769544082, COSV62390054; called by muse, mutect2, varscan2
- LACTBL1 | c.611C>T p.S204L (on ENST00000618559; = p.S249L on NM_001289974.2) | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1318546041; called by muse, mutect2, varscan2
- LAMA5 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749953963; called by muse, mutect2, varscan2
- LARGE1 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs146923365; called by muse, varscan2
- LARP1 | c.2702G>A p.R901Q (on ENST00000518297 / NM_033551.3; = p.R824Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/344 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757450704, COSV60427870; called by muse, mutect2, varscan2
- LARP4B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866154645, COSV60223537; called by muse, mutect2, varscan2
- LCE2A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs753692865, COSV64226821; called by muse, mutect2, varscan2
- LCMT2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs746410015; called by muse, mutect2, varscan2
- LDLR | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs770696696, CM091471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEFTY1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1410615103; called by muse, mutect2, varscan2
- LHFPL5 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs376479168; called by muse, mutect2, varscan2
- LIFR | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.315); catalogued as COSV54691142; called by muse, mutect2, varscan2
- LILRA1 | c.72G>A p.G24= | Splice Region (SNP) | VAF 17/169 reads (10%) | catalogued as rs765286954, COSV99251940; called by muse, mutect2
- LILRA4 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs750275949, COSV99392780; called by muse, mutect2, varscan2
- LILRB4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs145519196, COSV54409351; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 116/456 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs369219844; called by muse, mutect2, varscan2
- LINGO4 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs748289467; called by muse, mutect2, varscan2
- LIPG | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs536799767, COSV54296081; called by muse, mutect2, varscan2
- LKAAEAR1 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as rs1055207954; called by muse, mutect2, varscan2
- LMAN1L | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs202021967; called by muse, mutect2, varscan2
- LMAN2L | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748501432; called by muse, mutect2, varscan2
- LMLN2 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 88/469 reads (19%) | catalogued as rs987609587; called by muse, mutect2, varscan2
- LMX1B | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.616); catalogued as rs765969991; called by muse, mutect2, varscan2
- LONP1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as rs149596661; called by muse, mutect2, varscan2
- LOXHD1 | c.5474G>A p.R1825Q (on ENST00000642948; = p.R1763Q on NM_144612.7) | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs771185362; called by muse, mutect2, varscan2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 30/163 reads (18%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- LRP1 | c.11062G>A p.E3688K | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as rs201541007; called by muse, mutect2, varscan2
- LRP1B | c.10454del p.N3485Tfs*33 | Frame Shift Del (DEL) | VAF 90/379 reads (24%) | catalogued as rs79925984; called by mutect2, varscan2
- LRP2 | c.13832C>T p.A4611V | Missense Mutation (SNP) | VAF 94/438 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs529198764, COSV55540455; called by muse, mutect2, varscan2
- LRP2 | c.4478C>T p.A1493V | Missense Mutation (SNP) | VAF 73/400 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs748382645, COSV55565358; called by muse, varscan2
- LRP4 | c.5498G>A p.R1833Q | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.921); catalogued as rs771256759, COSV66135635; called by muse, mutect2, varscan2
- LRP4 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs775191643; called by muse, mutect2, varscan2
- LRRC14 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as rs1337625543, COSV52879975; called by muse, mutect2, varscan2
- LRRC27 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 110/467 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs112727561; called by muse, mutect2, varscan2
- LRRC37A3 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 94/678 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1193621508; called by muse, varscan2
- LRRC49 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.805); catalogued as rs767471553; called by muse, mutect2, varscan2
- LRRC4B | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs1276337308, COSV100976105; called by muse, mutect2, varscan2
- LRRC4C | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 94/500 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.54); catalogued as rs201412968, COSV53425400, COSV53430470; called by muse, varscan2
- LRRC7 | c.1480C>T p.R494C (on ENST00000651989 / NM_001370785.2; = p.R461C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765562100; called by muse, mutect2, varscan2
- LRWD1 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs150396748; called by muse, mutect2, varscan2
- LSM10 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as rs943465242; called by muse, varscan2
- LSM11 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs769770410, COSV53848901; called by muse, mutect2, varscan2
- LZIC | c.570del p.K190Nfs*16 | Frame Shift Del (DEL) | VAF 66/297 reads (22%) | catalogued as rs753028254; called by mutect2, varscan2
- LZTS1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.518); catalogued as rs1259821365; called by muse, mutect2, varscan2
- MAD1L1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs971692328; called by muse, mutect2, varscan2
- MAG | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs372192843; called by muse, mutect2, varscan2
- MAGEB6B | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1346788256, COSV69689992; called by muse, mutect2, varscan2
- MAGI2 | c.4112C>T p.A1371V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs13438363; called by muse, mutect2, varscan2
- MALRD1 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 112/420 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs1282298965; called by muse, mutect2, varscan2
- MALSU1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 71/383 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747613839, COSV54978160; called by muse, mutect2, varscan2
- MAMDC4 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1383747941, COSV56031702; called by muse, mutect2, varscan2
- MAN1B1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 80/351 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1488519885; called by muse, mutect2, varscan2
- MAN2A2 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144478704; called by muse, mutect2, varscan2
- MAN2A2 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 76/323 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs146996561; called by muse, mutect2, varscan2
- MAN2B2 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs569059179; called by muse, mutect2, varscan2
- MAN2C1 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as rs778458430, COSV51237082; called by muse, mutect2, varscan2
- MAP1S | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773801022; called by muse, mutect2, varscan2
- MAP2K5 | c.1306C>T p.R436W (on ENST00000178640 / NM_145160.3; = p.R426W on NM_002757.4) | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs762647820; called by muse, mutect2, varscan2
- MAP3K9 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs961518449; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 33/169 reads (20%) | catalogued as rs765962881; called by mutect2, varscan2
- MAPK7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); catalogued as rs748679283; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs763939482, COSV51726366; called by muse, varscan2
- MARCHF1 | c.680G>A p.R227H (on ENST00000274056; = p.R210H on NM_017923.4) | Missense Mutation (SNP) | VAF 134/636 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs779641825; called by muse, mutect2, varscan2
- MARF1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 130/628 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs201651611; called by muse, mutect2, varscan2
- MATN2 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774927507, COSV54714909; called by muse, varscan2
- MATN2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs200270504; called by muse, mutect2, varscan2
- MBOAT2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 155/645 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471364240, COSV60007642; called by muse, mutect2, varscan2
- MC1R | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs774680166, COSV59626514; called by muse, mutect2, varscan2
- MCCC2 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV60157586; called by muse, mutect2, varscan2
- MCM2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273687863; called by muse, mutect2, varscan2
- MCM2 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768322698; called by muse, mutect2, varscan2
- MCM3 | c.454G>A p.V152I (on ENST00000229854 / NM_001366374.2; = p.V142I on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/374 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs1033238760, COSV57719478; called by muse, mutect2, varscan2
- MDC1 | c.5869C>T p.R1957C | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770859881; called by muse, mutect2, varscan2
- MDH1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV51862786; called by mutect2, varscan2
- MDN1 | c.4616G>A p.R1539Q | Missense Mutation (SNP) | VAF 53/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65520068; called by muse, mutect2, varscan2
- MED1 | c.4064G>A p.R1355H | Missense Mutation (SNP) | VAF 85/419 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771798336; called by muse, mutect2, varscan2
- MEF2B | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs750716565; called by muse, mutect2, varscan2
- MEF2D | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752408015, COSV61730368; called by muse, mutect2, varscan2
- MEGF10 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 113/453 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs754183529; called by muse, mutect2, varscan2
- MEGF6 | c.4445G>A p.G1482E | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1202873987; called by muse, mutect2, varscan2
- MEIOB | c.1del p.M1? | Frame Shift Del (DEL) | VAF 54/298 reads (18%) | catalogued as rs756894401; called by mutect2, varscan2
- MEIS2 | c.562G>A p.V188I (on ENST00000561208 / NM_170675.5; = p.V175I on NM_002399.3) | Missense Mutation (SNP) | VAF 90/447 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs762490597; called by muse, mutect2, varscan2
- METTL21A | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 101/438 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374826319; called by muse, mutect2, varscan2
- METTL7B | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57692121; called by muse, mutect2, varscan2
- MFGE8 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs568619975; called by muse, mutect2, varscan2
- MFHAS1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52284172; called by muse, mutect2, varscan2
- MFSD2B | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 64/285 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs756008102; called by muse, mutect2, varscan2
- MGAT4B | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs748605549, COSV99482332; called by muse, mutect2, varscan2
- MGLL | c.491C>T p.A164V (on ENST00000398104 / NM_001003794.2; = p.A174V on NM_007283.6) | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs374353919; called by muse, mutect2, varscan2
- MGLL | c.392C>T p.T131M (on ENST00000398104 / NM_001003794.2; = p.T141M on NM_007283.6) | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs773416847; called by muse, varscan2
- MINAR1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 83/370 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775338460, COSV59582058; called by muse, mutect2, varscan2
- MIS18BP1 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 70/416 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60374191; called by muse, mutect2, varscan2
- MLIP | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs145131028; called by muse, mutect2, varscan2
- MLLT10 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 88/460 reads (19%) | catalogued as rs1179221232, COSV57004712; called by muse, mutect2, varscan2
- MMEL1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs372890618; called by muse, mutect2, varscan2
- MMP7 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 105/431 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs542899524, COSV52772100; called by muse, varscan2
- MORC2 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 118/537 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs1034098965; called by muse, mutect2, varscan2
- MPEG1 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 87/375 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs369599067; called by muse, mutect2, varscan2
- MPRIP | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1175028801; called by muse, mutect2, varscan2
- MRC2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.823); catalogued as rs368122647; called by muse, mutect2, varscan2
- MRGPRX1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 83/695 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs760583024, COSV57109647; called by muse, mutect2, varscan2
- MRM3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs761278369, COSV58680856; called by muse, mutect2, varscan2
- MROH2A | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1201608726; called by muse, mutect2, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 45/239 reads (19%) | catalogued as rs1558718327, COSV62567684; called by mutect2, varscan2
- MRPL21 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 79/354 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201987235, COSV62913775; called by muse, mutect2, varscan2
- MRPS18B | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs1197838687; called by muse, mutect2, varscan2
- MSANTD4 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 103/470 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs1177741904; called by muse, mutect2, varscan2
- MST1R | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 77/297 reads (26%) | catalogued as rs1216259052, COSV56565834; called by muse, mutect2, varscan2
- MTHFR | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200056619, CM127686; called by muse, mutect2, varscan2
- MTMR12 | c.2065del p.Q689Rfs*8 | Frame Shift Del (DEL) | VAF 56/278 reads (20%) | catalogued as rs1166239304; called by mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 55/315 reads (17%) | catalogued as rs1563799887; called by mutect2, varscan2
- MTSS2 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs374985478; called by muse, mutect2, varscan2
- MTUS2 | c.3565C>T p.R1189W (on ENST00000612955 / NM_001366650.1; = p.R168W on NM_015233.6) | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753762677, COSV60158423; called by muse, mutect2, varscan2
- MUC17 | c.13469C>T p.T4490M | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs534194993, COSV60292396; called by muse, mutect2, varscan2
- MUC2 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT tolerated (0.17); catalogued as rs549661080; called by muse, mutect2, varscan2
- MUC20 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 127/988 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs372880164; called by muse, varscan2
- MUC21 | c.1612dup p.H538Pfs*8 | Frame Shift Ins (INS) | VAF 80/388 reads (21%) | catalogued as rs1242962833; called by mutect2, varscan2
- MUC4 | c.9215C>T p.P3072L | Missense Mutation (SNP) | VAF 83/761 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as rs774537374; called by muse, varscan2
- MUC5B | c.14862C>T p.P4954= | Splice Region (SNP) | VAF 52/180 reads (29%) | catalogued as rs113593046; called by muse, varscan2
- MYADM | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.916); catalogued as rs150025165; called by muse, mutect2, varscan2
- MYH11 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.226); catalogued as COSV55555943; called by muse, mutect2, varscan2
- MYH13 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 80/369 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52836475; called by muse, mutect2, varscan2
- MYH15 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 92/422 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749863386, COSV56323954; called by muse, mutect2, varscan2
- MYH3 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs767298033; called by muse, mutect2, varscan2
- MYH4 | c.4021C>T p.R1341C | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs765219970; called by muse, mutect2, varscan2
- MYH7 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs558673680; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs199736263; ClinVar: uncertain significance; called by muse, varscan2
- MYLK | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs1052930526, COSV60610401; called by muse, varscan2
- MYO15A | c.5758C>T p.R1920W | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs771986838; called by muse, mutect2, varscan2
- MYO16 | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 72/403 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as rs771546307, COSV99194899; called by muse, mutect2, varscan2
- MYO18B | c.7141C>T p.R2381C | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs769468687; called by muse, mutect2, varscan2
- MYO1B | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs746455451, COSV100269349, COSV100269897; called by muse, mutect2, varscan2
- MYO1C | c.2812C>T p.R938W (on ENST00000648651 / NM_001080779.2; = p.R903W on NM_033375.5) | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761228547, COSV100704382; called by muse, mutect2, varscan2
- MYO1C | c.205C>T p.R69W (on ENST00000648651 / NM_001080779.2; = p.R34W on NM_033375.5) | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs550955554; called by muse, mutect2, varscan2
- MYO1H | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747138203, COSV60442963; called by muse, mutect2, varscan2
- MYO3A | c.3574dup p.M1192Nfs*3 | Frame Shift Ins (INS) | VAF 96/414 reads (23%) | catalogued as rs757810767; called by mutect2, varscan2
- MYO7B | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 85/322 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756819806; called by muse, mutect2, varscan2
- MYOM2 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 95/500 reads (19%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.491); catalogued as rs567616599, COSV100038624; called by muse, mutect2, varscan2
- MYOM3 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs746030427, COSV58393914; called by muse, mutect2, varscan2
- MYSM1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs780998329, COSV101284060; called by muse, mutect2, varscan2
- MYT1 | c.2795C>T p.S932L | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs367957600; called by muse, mutect2, varscan2
- N4BP2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 117/471 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748112633, COSV99788250; called by muse, mutect2, varscan2
- N4BP2 | c.2981C>T p.T994M | Missense Mutation (SNP) | VAF 102/455 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as rs199590556; called by muse, mutect2, varscan2
- N4BP2L2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570313447, COSV57228462; called by muse, mutect2, varscan2
- NACC2 | c.1691del p.G564Afs*37 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | catalogued as COSV53199188; called by mutect2, varscan2
- NADSYN1 | c.1687C>A p.L563M | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100034346; called by muse, mutect2, varscan2
- NAPA | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.461); catalogued as rs1313967014; called by muse, mutect2, varscan2
- NAT10 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as rs748227063, COSV57664058; called by muse, mutect2, varscan2
- NAT14 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.375); catalogued as rs1359701141; called by muse, mutect2, varscan2
- NAV1 | c.5220C>T p.I1740= | Splice Region (SNP) | VAF 47/183 reads (26%) | catalogued as rs532738759; called by muse, mutect2, varscan2
- NBAS | c.1141del p.I381Sfs*10 | Frame Shift Del (DEL) | VAF 50/248 reads (20%) | catalogued as rs772472509; called by mutect2, varscan2
- NBEAL2 | c.2612G>A p.R871H | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759606842, COSV99437017; called by muse, mutect2, varscan2
- NCAN | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs370172612; called by muse, mutect2, varscan2
- NCBP2AS2 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs370800730; called by muse, mutect2, varscan2
- NCKAP5L | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs1212708146; called by muse, varscan2
- NCKIPSD | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748596595; called by muse, mutect2, varscan2
- NCOA2 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 122/562 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267601983, COSV71763821; called by muse, mutect2, varscan2
- NEDD4L | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 112/490 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs375068828; called by muse, varscan2
- NEDD9 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 101/446 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760782051, COSV65219135; called by muse, mutect2, varscan2
- NEURL1 | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100872634; called by muse, mutect2, varscan2
- NEURL4 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs767504785, COSV59764186; called by muse, mutect2, varscan2
- NEURL4 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs766371638; called by muse, mutect2, varscan2
- NFAT5 | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 134/581 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as rs149255851, COSV63026160; called by muse, varscan2
- NFATC3 | c.2068del p.S690Afs*12 | Frame Shift Del (DEL) | VAF 72/320 reads (23%) | catalogued as COSV60473781; called by mutect2, varscan2
- NFKBIL1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs199596929; called by muse, varscan2
1,862 further variants in this file (1,136 protein-altering or splice-affecting, 651 silent, 75 other) are not listed here.
